HCMI case HCM-EXPT-1040-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/63e7cf10-56ac-40c9-90b0-e78a99af789a

Demographics
Sex at birth: female; Year of birth: 1964.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 54.6 years (19,950 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1040-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1040-C50-01A-01-S1-HE: Section location: Top; Percent tumor cells: 47; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 51; Percent lymphocyte infiltration: 14; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1040-C50-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 43; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 53; Percent lymphocyte infiltration: 42; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
